Somatic mutation profile of tumor specimen C3L-06028-05 (aliquot CPT0361290009) from CPTAC case C3L-06028, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.4 years (21,694 days).
Specimen C3L-06028-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adb80c7c-1d03-49b0-bf9c-3eb8916deba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06028-31 (Blood Derived Normal), aliquot CPT0361350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30954db7-6bd5-4356-aae1-26e70d207bbf

The open-access MAF lists 492 somatic variants for this specimen: 328 protein-altering or splice-affecting, 144 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 289, Silent 144, Nonsense Mutation 24, Intron 11, Splice Region 8, Splice Site 4, 3'UTR 4, 3'Flank 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.1855G>A p.G619R | Missense Mutation (SNP) | VAF 95/321 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773515249, CM143820; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- DDX3X | c.118C>T p.P40S (on ENST00000399959; = p.P41S on NM_001356.5) | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1064793796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10612C>T p.R3538* | Nonsense Mutation (SNP) | VAF 51/204 reads (25%) | catalogued as rs878853413, CM159124, COSV56359453; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1432A>G p.N478D | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs1395507452; called by muse, mutect2, varscan2
- ACAN | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 214/772 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1002450754; called by muse, mutect2, varscan2
- ADAM2 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.232); catalogued as rs1317686368, COSV99697408; called by muse, mutect2, varscan2
- ADAM22 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55979935; called by muse, mutect2, varscan2
- AL121899.2 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 177/521 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV101198352; called by muse, mutect2, varscan2
- AMER1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 146/247 reads (59%) | catalogued as COSV57666208; called by muse, mutect2, varscan2
- ANGPTL2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs747522447; called by muse, mutect2, varscan2
- ANGPTL4 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs534265654; called by muse, mutect2, varscan2
- AOC1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 164/1614 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV100711065; called by muse, mutect2
- AREG | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as rs1439656918, COSV52644968; called by muse, mutect2, varscan2
- ARHGAP11A | c.1810T>C p.S604P | Missense Mutation (SNP) | VAF 169/583 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1428375140; called by muse, mutect2, varscan2
- ARHGDIG | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs140573990; called by muse, mutect2, varscan2
- ARHGEF7 | c.1474G>A p.G492R (on ENST00000375741 / NM_001113511.2; = p.G314R on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.442); catalogued as rs1321905052; called by muse, mutect2, varscan2
- ARSB | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 81/385 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53723665; called by muse, mutect2, varscan2
- ASCC2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.229); catalogued as rs966876126, COSV57076405; called by muse, mutect2, varscan2
- ASH1L | c.4381C>T p.L1461F | Missense Mutation (SNP) | VAF 90/358 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs753849025; called by muse, mutect2, varscan2
- ATF7IP | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as rs757253720, COSV53767787; called by muse, mutect2, varscan2
- ATP8A1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs751157914, COSV52533125, COSV52543860; called by muse, mutect2, varscan2
- ATP8A1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV52531272; called by muse, mutect2, varscan2
- BCAN | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 90/352 reads (26%) | catalogued as rs769390629, COSV100228110; called by muse, mutect2, varscan2
- BEND2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV66216203; called by muse, mutect2, varscan2
- C10orf120 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776437508, COSV100271717; called by muse, mutect2, varscan2
- C1orf226 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768005602; called by muse, mutect2, varscan2
- CACNA2D3 | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 53/322 reads (16%) | catalogued as rs1553827258, COSV55589547; called by muse, mutect2, varscan2
- CBFA2T3 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 136/469 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs774310781, COSV51922943, COSV51929210; called by muse, mutect2, varscan2
- CCDC39 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); catalogued as rs540660862, COSV56479847, COSV56482766, COSV56484585; called by muse, mutect2, varscan2
- CCNJL | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs755233695, COSV57446204; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 73/313 reads (23%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by muse, mutect2, varscan2
- CELA3A | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 80/410 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs779573222; called by muse, mutect2, varscan2
- CELSR1 | c.4129C>T p.R1377C | Missense Mutation (SNP) | VAF 109/458 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); catalogued as rs556344390, COSV99418014; called by muse, mutect2, varscan2
- CFAP44 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs199722807; called by muse, mutect2, varscan2
- CFAP74 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs372544678, COSV54568075; called by muse, mutect2, varscan2
- CFHR5 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs774353375, COSV56817855; called by muse, mutect2, varscan2
- CGNL1 | c.2577A>T p.E859D | Missense Mutation (SNP) | VAF 227/516 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV55575744; called by muse, mutect2, varscan2
- CMKLR1 | c.997C>T p.R333C (on ENST00000312143 / NM_001142344.2; = p.R331C on NM_004072.3) | Missense Mutation (SNP) | VAF 108/366 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs370160040, COSV56437267; called by muse, mutect2, varscan2
- COL22A1 | c.3484G>A p.G1162R | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57348066; called by muse, mutect2, varscan2
- COL22A1 | c.846G>A p.E282= | Splice Region (SNP) | VAF 60/151 reads (40%) | catalogued as COSV57357089; called by muse, mutect2, varscan2
- CRAMP1 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 139/477 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs373720836; called by muse, mutect2, varscan2
- CRB1 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66330947; called by muse, mutect2, varscan2
- CREB3L2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 86/723 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs778038461, COSV57794142; called by muse, mutect2, varscan2
- CRNKL1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 234/634 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs775584333, COSV55636432; called by muse, mutect2, varscan2
- CSMD1 | c.7865C>T p.S2622L (on ENST00000520002; = p.S2621L on NM_033225.6) | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377667100, COSV59317265; called by muse, mutect2, varscan2
- CTSG | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as rs1416976566; called by muse, mutect2, varscan2
- CYP2C9 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99582805; called by muse, mutect2, varscan2
- DACT1 | c.2285G>A p.S762N | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1228822793; called by muse, mutect2, varscan2
- DCC | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs376603147; called by muse, mutect2, varscan2
- DCC | c.3811G>A p.G1271R | Missense Mutation (SNP) | VAF 125/466 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs949823133; called by muse, mutect2, varscan2
- DISP3 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99037588; called by muse, mutect2, varscan2
- DNAH10 | c.1537C>T p.R513W (on ENST00000409039; = p.R452W on NM_207437.3) | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs762207670, COSV68999026; called by muse, mutect2, varscan2
- DOCK5 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs188912237; called by muse, mutect2, varscan2
- DSCAM | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 118/392 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101261791; called by muse, mutect2, varscan2
- ERICH1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs201709114; called by muse, mutect2, varscan2
- ESPNL | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 145/513 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs570616030, COSV58032853; called by muse, mutect2, varscan2
- FAF1 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65642437; called by muse, mutect2, varscan2
- FAM184B | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs995396007; called by muse, mutect2, varscan2
- FKBP6 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782776540, COSV52723525; called by muse, mutect2, varscan2
- FRG2B | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 37/742 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1186277680; called by muse, mutect2
- GCK | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.956); catalogued as COSV67885065; called by muse, mutect2, varscan2
- GFM1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs747208903; called by muse, mutect2, varscan2
- GOLGA2 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1423684962; called by muse, mutect2, varscan2
- GRIA2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52385092; called by muse, mutect2, varscan2
- GRXCR1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs569193097, CM153970, COSV67670071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTDC1 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs149430325; called by muse, mutect2, varscan2
- HECW1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV67830993; called by muse, mutect2, varscan2
- HERC2 | c.7460G>A p.G2487E | Missense Mutation (SNP) | VAF 181/489 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV99875809; called by muse, mutect2, varscan2
- HSD3B7 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.196); catalogued as COSV52682841; called by muse, mutect2, varscan2
- HYDIN | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751217729; called by muse, mutect2, varscan2
- IGBP1P2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV53617792; called by muse, mutect2, varscan2
- IL12RB2 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780971273; called by muse, mutect2, varscan2
- INHBA | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs778711643; called by muse, mutect2, varscan2
- INSYN2B | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56987005; called by muse, mutect2, varscan2
- ITGA10 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 103/338 reads (30%) | catalogued as rs199638228, COSV65196125; called by muse, mutect2, varscan2
- ITLN1 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1482576231; called by muse, mutect2, varscan2
- KIAA1217 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770707771, COSV100286920; called by muse, mutect2, varscan2
- KIF4B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs770712289, COSV70528176; called by muse, mutect2, varscan2
- KIRREL2 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 127/501 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs142632409; called by muse, mutect2, varscan2
- KLHDC7A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 148/474 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs780616009, COSV68769217; called by muse, mutect2, varscan2
- KMT2B | c.4097C>T p.A1366V | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs868585553; called by muse, mutect2, varscan2
- KRBA1 | c.3080G>A p.W1027* | Nonsense Mutation (SNP) | VAF 85/1109 reads (8%) | catalogued as COSV99753011; called by muse, mutect2
- KRT26 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as COSV56973018; called by muse, mutect2, varscan2
- LILRB4 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 87/398 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs142773263; called by muse, mutect2, varscan2
- LMO7 | c.3005T>C p.M1002T (on ENST00000357063; = p.M683T on NM_005358.5) | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs201710176; called by muse, mutect2, varscan2
- LMX1A | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99671909; called by muse, varscan2
- LRRC37A3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 118/1076 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs748308700; called by muse, mutect2, varscan2
- MAGI3 | c.3938G>A p.S1313N | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs376549597; called by muse, mutect2, varscan2
- MAMDC2 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.243); catalogued as COSV65858592; called by muse, mutect2, varscan2
- MARCHF8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 130/417 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs576158640; called by muse, mutect2, varscan2
- MICALL2 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 129/439 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs757116054, COSV52518295; called by muse, mutect2, varscan2
- MSTO1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs1328796952, COSV55471096; called by muse, mutect2, varscan2
- MUC16 | c.28790C>T p.S9597F | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs764310693, COSV67467799; called by muse, mutect2, varscan2
- MUC16 | c.8303C>T p.S2768L | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs867486850; called by muse, mutect2, varscan2
- MYEOV | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs1301433844; called by muse, mutect2, varscan2
- MYH2 | c.2943G>A p.V981= | Splice Region (SNP) | VAF 64/240 reads (27%) | catalogued as COSV55432675; called by muse, mutect2, varscan2
- MYOC | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 82/348 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1344039930, CM981343, COSV50678494; called by muse, mutect2, varscan2
- NONO | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52136998, COSV52138484; called by muse, mutect2, varscan2
- NPAP1 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 306/684 reads (45%) | catalogued as rs866413377, COSV61503908, COSV61505760; called by muse, mutect2, varscan2
- NPIPB8 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as rs1385678872; called by mutect2, varscan2
- NR2E1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1309446949; called by muse, mutect2, varscan2
- ODF4 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs369506738; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 66/516 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by muse, mutect2, varscan2
- OR1L3 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 93/354 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59169893; called by muse, mutect2, varscan2
- OR1M1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1275667816, COSV70036633; called by muse, mutect2, varscan2
- OR4K5 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV60002766, COSV60004744; called by muse, mutect2, varscan2
- OR51F2 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100437857; called by muse, varscan2
- OR51G1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV58969228; called by muse, mutect2, varscan2
- OR6C76 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 92/338 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100094166; called by muse, mutect2, varscan2
- OS9 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs574105758; called by muse, mutect2, varscan2
- PCDHB16 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782772782, COSV53367448, COSV99500877; called by muse, mutect2, varscan2
- PCSK2 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 191/593 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV52725663, COSV52742339; called by muse, mutect2, varscan2
- PDIA6 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 95/332 reads (29%) | catalogued as rs527557948; called by muse, mutect2, varscan2
- PKP2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV50741306; called by muse, mutect2, varscan2
- PLCG2 | c.3491C>T p.S1164F | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs781497956, COSV63868513; called by muse, mutect2, varscan2
- PLCH1 | c.2012C>T p.P671L (on ENST00000340059 / NM_001130960.2; = p.P683L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs999296824; called by muse, mutect2, varscan2
- PMFBP1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs139406797, COSV52827974, COSV99401084; called by muse, mutect2, varscan2
- PNMA2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 95/363 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1338475741, COSV72908483; called by muse, mutect2, varscan2
- POFUT1 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 158/490 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs749782165; called by muse, varscan2
- POU6F2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 69/487 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs1301179209; called by muse, mutect2, varscan2
- PPP1R26 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as rs774558866; called by muse, mutect2, varscan2
- PTGFR | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 57/219 reads (26%) | catalogued as COSV66114596; called by muse, mutect2, varscan2
- PTPN13 | c.5465C>T p.A1822V (on ENST00000411767 / NM_080683.3; = p.A1803V on NM_006264.3) | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336111241; called by muse, mutect2, varscan2
- RAP1GAP | c.641A>T p.N214I | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs74369395; called by muse, mutect2, varscan2
- RIN1 | c.2213A>T p.D738V | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV60927282; called by muse, mutect2, varscan2
- RNF213 | c.5447C>T p.P1816L | Missense Mutation (SNP) | VAF 90/355 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1353859171; called by muse, mutect2, varscan2
- RSPO2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139268055; called by muse, mutect2, varscan2
- RXFP2 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs747018523, COSV100034008; called by muse, mutect2, varscan2
- SCN5A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61114841; called by muse, mutect2, varscan2
- SGPP1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99905704, COSV99905940; called by muse, mutect2, varscan2
- SLC22A6 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 97/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148475665; called by muse, mutect2, varscan2
- SLC6A13 | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV58256767; called by muse, mutect2, varscan2
- SLC8A1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60496513; called by muse, mutect2, varscan2
- SORCS3 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1322941069, COSV63803440; called by muse, mutect2, varscan2
- SRRT | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 122/441 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs530416504; called by muse, mutect2, varscan2
- ST3GAL5 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.154); catalogued as rs952271385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST8SIA4 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 67/354 reads (19%) | PolyPhen benign (0.217); catalogued as COSV99185323; called by muse, mutect2, varscan2
- STAB2 | c.2867C>T p.S956L | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV101185685; called by muse, mutect2, varscan2
- STON2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as rs745574107; called by muse, mutect2, varscan2
- TENM2 | c.3671C>T p.S1224F (on ENST00000518659 / NM_001122679.2; = p.S992F on NM_001080428.3) | Missense Mutation (SNP) | VAF 191/498 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV69122400; called by muse, mutect2, varscan2
- TICAM1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 102/372 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as rs749105540; called by muse, mutect2, varscan2
- TINAG | c.749-1G>A p.X250_splice | Splice Site (SNP) | VAF 47/192 reads (24%) | catalogued as rs758939771; called by muse, mutect2, varscan2
- TLL1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50271777; called by muse, mutect2
- TLL1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs1411322301, COSV50261775; called by muse, mutect2, varscan2
- TMEM205 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 101/411 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs753913306, COSV55793339; called by muse, mutect2, varscan2
- TMUB1 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 136/1541 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52542793; called by muse, mutect2
- TONSL | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs753001104, COSV101340263; called by muse, mutect2, varscan2
- TP63 | c.767-1G>A p.X256_splice | Splice Site (SNP) | VAF 46/192 reads (24%) | catalogued as COSV53209156; called by muse, mutect2, varscan2
- TPTE | c.636A>C p.K212N (on ENST00000618007 / NM_199261.4; = p.K194N on NM_199259.4) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as rs770116757; called by muse, mutect2, varscan2
- TRAF3IP3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs1357609595, COSV50555199; called by muse, mutect2, varscan2
- TRPV6 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 90/813 reads (11%) | catalogued as rs768054539; called by muse, mutect2, varscan2
- TTYH1 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 115/452 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as rs1205960225; called by muse, mutect2, varscan2
- UNC80 | c.3880G>A p.G1294R | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs1378037500, COSV55887866, COSV55887990; called by muse, mutect2, varscan2
- VCAM1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54120198; called by muse, mutect2, varscan2
- VCPIP1 | c.2079T>G p.I693M | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762037002; called by muse, mutect2, varscan2
- VSTM2L | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 243/704 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs766602517; called by muse, mutect2, varscan2
- WDR91 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 85/607 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs780856081; called by muse, mutect2, varscan2
- WFDC12 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65660949; called by muse, mutect2, varscan2
- XYLT1 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs748773365, COSV54477573, COSV54482794; called by muse, mutect2, varscan2
- ZC3H7B | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 104/474 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as COSV60965074; called by muse, mutect2, varscan2
- ZNF138 | c.908G>A p.G303E (on ENST00000307355 / NM_001367572.1; = p.G277E on NM_006524.4) | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1198286468; called by muse, mutect2, varscan2
- ZNF329 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs759885199, COSV63771773; called by muse, mutect2, varscan2
- ZNF334 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 205/555 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV104417916; called by muse, mutect2, varscan2
- ZNF516 | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 120/457 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs983215262; called by muse, mutect2, varscan2
- ZNF628 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99219899; called by muse, mutect2, varscan2
- ZNF735 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as COSV70034797, COSV70035931; called by muse, mutect2, varscan2
- ABCC3 | c.2875T>C p.F959L | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- AC097637.1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 83/343 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS6 | c.3106C>T p.L1036F | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AGPS | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 146/460 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGTR1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ALPK2 | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 111/396 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMIGO1 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 108/397 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AP3B2 | c.2429A>T p.D810V | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP30 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB3 | c.1096_1106del p.R366Lfs*10 | Frame Shift Del (DEL) | VAF 65/255 reads (25%) | called by mutect2, pindel, varscan2
- ASTN2 | c.3482C>T p.P1161L (on ENST00000313400 / NM_001365069.1; = p.P1110L on NM_014010.5) | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ATP1A1 | c.501G>A p.Q167= | Splice Region (SNP) | VAF 58/154 reads (38%) | called by muse, mutect2, varscan2
- ATP9B | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BAZ2A | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- C12orf45 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C2orf16 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- C6 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 173/395 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1B | c.207C>A p.F69L | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASC3 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, varscan2
- CCIN | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2
- CD7 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 144/533 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDK13 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 168/334 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDRT1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFHR5 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CHD4 | c.3058C>T p.P1020S (on ENST00000357008 / NM_001363606.2; = p.P1033S on NM_001273.5) | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CLDN10 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 110/375 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CNTNAP2 | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.031); called by muse, mutect2
- COL4A3 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 107/352 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CRAMP1 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 139/476 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYGB | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 70/290 reads (24%) | called by muse, mutect2, varscan2
- CTPS1 | c.1689C>T p.P563= | Splice Region (SNP) | VAF 71/208 reads (34%) | called by muse, mutect2, varscan2
- DDX53 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 80/148 reads (54%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGLUCY | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK8 | c.5248G>A p.E1750K | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- EIF3B | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMILIN1 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 91/394 reads (23%) | called by muse, mutect2, varscan2
- EPHX3 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- ERICH1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ESRRB | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 91/292 reads (31%) | called by muse, mutect2, varscan2
- FERMT3 | c.1447G>A p.G483S (on ENST00000279227 / NM_178443.3; = p.G479S on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/519 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FNDC3B | c.2776C>T p.L926F | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FRG2C | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 78/984 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FRY | c.7232_7233insT p.K2412Qfs*17 | Frame Shift Ins (INS) | VAF 47/210 reads (22%) | called by mutect2, pindel*, varscan2
- GABRR1 | c.351C>T p.D117= | Splice Region (SNP) | VAF 75/214 reads (35%) | called by muse, mutect2, varscan2
- GCM2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI2 | c.2530G>A p.D844N (on ENST00000361492 / NM_001374353.1; = p.D861N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/558 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GLRB | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGA2 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GRIK2 | c.1494G>A p.W498* | Nonsense Mutation (SNP) | VAF 48/214 reads (22%) | called by muse, mutect2, varscan2
- GRIP2 | c.988G>A p.D330N (on ENST00000619221; = p.D233N on NM_001080423.4) | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H2BC12 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 116/458 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- HAL | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HBD | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ2 | c.4279A>G p.I1427V (on ENST00000467148 / NM_001037335.2; = p.I858V on NM_033405.3) | Missense Mutation (SNP) | VAF 228/639 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HSPA12B | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 167/450 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HYDIN | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- IL27RA | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INTS5 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 101/418 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IQGAP3 | c.2660C>G p.S887C | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITIH1 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITPR3 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITSN1 | c.4075-1G>A p.X1359_splice | Splice Site (SNP) | VAF 42/233 reads (18%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- JAKMIP3 | c.1640A>T p.Q547L | Missense Mutation (SNP) | VAF 121/411 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- JPH2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 282/768 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KCNK5 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KIAA0100 | c.5910G>A p.K1970= | Splice Region (SNP) | VAF 66/234 reads (28%) | called by muse, mutect2, varscan2
- KIAA0825 | c.2996G>A p.R999K | Missense Mutation (SNP) | VAF 150/397 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KLHL26 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- KMT5B | c.1910G>A p.G637E | Missense Mutation (SNP) | VAF 90/383 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRBA1 | c.3081G>A p.W1027* | Nonsense Mutation (SNP) | VAF 84/1092 reads (8%) | called by muse, mutect2
- KRT76 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 155/499 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KRTAP19-4 | c.110A>T p.Y37F | Missense Mutation (SNP) | VAF 109/397 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP2-4 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 100/477 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LAMA3 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- LMNA | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LMX1B | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 124/454 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2
- LPIN2 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MATN3 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 91/411 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATN4 | c.1565C>T p.A522V (on ENST00000372754; = p.A481V on NM_003833.4) | Missense Mutation (SNP) | VAF 153/493 reads (31%) | PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEX3D | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 141/502 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MGA | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM2 | c.2536C>T p.L846F | Missense Mutation (SNP) | VAF 78/533 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MIOS | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.139); called by muse, mutect2
- MIS18BP1 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MKI67 | c.7961C>T p.P2654L | Missense Mutation (SNP) | VAF 95/424 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2
- MTA1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MYH1 | c.3920G>A p.R1307K | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MYO15B | c.7567C>T p.L2523F | Missense Mutation (SNP) | VAF 121/390 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- MYO5B | c.4399C>T p.Q1467* | Nonsense Mutation (SNP) | VAF 83/341 reads (24%) | called by muse, mutect2, varscan2
- NANOS3 | c.126+8C>T | Splice Region (SNP) | VAF 113/416 reads (27%) | called by muse, mutect2, varscan2
- NDST4 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NELFA | c.619C>T p.P207S (on ENST00000542778; = p.P196S on NM_005663.5) | Missense Mutation (SNP) | VAF 95/401 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NEU3 | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- NRIP2 | c.495G>A p.K165= | Splice Region (SNP) | VAF 64/214 reads (30%) | called by muse, mutect2, varscan2
- OLFML3 | c.1033A>T p.I345F | Missense Mutation (SNP) | VAF 131/486 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- OR51G2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- OR6C65 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OTOP3 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTUD7B | c.2457T>A p.C819* | Nonsense Mutation (SNP) | VAF 85/333 reads (26%) | called by muse, mutect2, varscan2
- OTUD7B | c.2456G>C p.C819S | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- P2RY14 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PC | c.2116T>A p.Y706N | Missense Mutation (SNP) | VAF 114/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PC | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA10 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 101/458 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PCDHB1 | c.1942C>T p.H648Y | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PDIA3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 180/443 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDIA6 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 96/333 reads (29%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLD4 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 89/380 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POM121L12 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 122/730 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- POMK | c.705_728del p.N235_V242del | In Frame Del (DEL) | VAF 52/330 reads (16%) | called by mutect2, varscan2
- POU6F1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PPARGC1B | c.2576C>T p.S859L | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRDM6 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 77/399 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PRSS58 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 88/614 reads (14%) | called by muse, mutect2, varscan2
- PSMB8 | c.241C>T p.Q81* (on ENST00000374882 / NM_148919.4; = p.Q77* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 135/510 reads (26%) | called by muse, mutect2, varscan2
- RAB9A | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RAD54L2 | c.3847C>T p.P1283S | Missense Mutation (SNP) | VAF 133/408 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI1 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RCSD1 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RUNDC3A | c.382T>A p.W128R | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- S100A8 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SARM1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SCN11A | c.1255A>G p.K419E | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN7A | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SET | c.190G>A p.E64K (on ENST00000372692 / NM_001374326.1; = p.E51K on NM_003011.4) | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SH3GL2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC34A1 | c.1346T>G p.I449S | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- SLITRK1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLTM | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 260/560 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SP7 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPAM1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRSF10 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STK33 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYMPK | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- TAGLN2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBC1D10A | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBCCD1 | c.1183T>C p.C395R | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCF25 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); called by muse, mutect2
- TDRD15 | c.2873C>T p.S958F | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TENT4A | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TGM5 | c.1349C>T p.S450F (on ENST00000220420 / NM_201631.4; = p.S368F on NM_004245.4) | Missense Mutation (SNP) | VAF 137/278 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THBS2 | c.2236A>G p.N746D | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TMC5 | c.1480G>A p.G494R (on ENST00000396229 / NM_001105248.1; = p.G248R on NM_024780.5) | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNRC6B | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- TPH1 | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TRAFD1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM2 | c.1217G>C p.R406T (on ENST00000437508; = p.R433T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- TTN | c.71180G>A p.G23727E (on ENST00000591111; = p.G16303E on NM_003319.4) | Missense Mutation (SNP) | VAF 80/304 reads (26%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA2 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 55/251 reads (22%) | called by muse, mutect2, varscan2
- USH2A | c.5930A>G p.E1977G | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VCPIP1 | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VWA3B | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WBP4 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- WDR19 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZBED9 | c.3185T>C p.L1062S | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ZBTB5 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 110/403 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP90 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF862 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 106/1350 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- AC098582.1 | c.525C>T p.F175= | Silent (SNP) | VAF 100/399 reads (25%) | called by muse, mutect2, varscan2
- ADAM8 | c.1971C>T p.F657= | Silent (SNP) | VAF 91/276 reads (33%) | catalogued as rs1250187140, COSV101291651; called by muse, mutect2, varscan2
- ADAMTS12 | c.2064G>A p.E688= | Silent (SNP) | VAF 167/381 reads (44%) | catalogued as rs1219327392; called by muse, mutect2, varscan2
- ADCK2 | c.1854C>T p.L618= | Silent (SNP) | VAF 88/1112 reads (8%) | called by muse, mutect2
- ADGRB2 | c.4608C>T p.S1536= (on ENST00000373658 / NM_001364857.2; = p.S1535= on NM_001294335.2) | Silent (SNP) | VAF 102/323 reads (32%) | called by muse, mutect2, varscan2
- ADSS1 | c.1149G>A p.G383= | Silent (SNP) | VAF 64/259 reads (25%) | catalogued as COSV58274891; called by muse, mutect2, varscan2
- AGAP6 | c.798C>T p.L266= (on ENST00000374056 / NM_001365867.1; = p.L289= on NM_001077665.2) | Silent (SNP) | VAF 153/533 reads (29%) | catalogued as rs782237119; called by muse, mutect2, varscan2
- AGTR1 | c.750C>T p.F250= | Silent (SNP) | VAF 48/232 reads (21%) | catalogued as COSV62557130, COSV62557404; called by muse, mutect2, varscan2
- ALMS1 | c.11535G>A p.R3845= | Silent (SNP) | VAF 105/429 reads (24%) | called by muse, mutect2, varscan2
- ALOX5 | c.1494G>A p.Q498= | Silent (SNP) | VAF 113/358 reads (32%) | catalogued as rs1448010866; called by muse, mutect2, varscan2
- AMACR | c.315C>T p.A105= | Silent (SNP) | VAF 75/392 reads (19%) | catalogued as rs756291524; called by muse, varscan2
- ANK3 | c.6303C>T p.S2101= | Silent (SNP) | VAF 82/292 reads (28%) | catalogued as COSV55058205; called by muse, mutect2, varscan2
- ANKFY1 | c.3084C>T p.F1028= (on ENST00000341657 / NM_001330063.2; = p.F1029= on NM_016376.5) | Silent (SNP) | VAF 79/243 reads (33%) | called by muse, mutect2, varscan2
- ANKRD12 | c.4338C>T p.S1446= | Silent (SNP) | VAF 65/297 reads (22%) | catalogued as rs150466710; called by muse, mutect2, varscan2
- ARHGAP19 | c.688T>C p.L230= | Silent (SNP) | VAF 102/357 reads (29%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.750C>T p.S250= | Silent (SNP) | VAF 109/455 reads (24%) | catalogued as rs11235721; called by muse, mutect2, varscan2
- ARL9 | c.723G>A p.K241= (on ENST00000640821 / NM_001363794.2; = p.K99= on NM_206919.2) | Silent (SNP) | VAF 90/302 reads (30%) | called by muse, mutect2, varscan2
- ARMC4 | c.2280C>T p.T760= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as rs571264531; called by muse, mutect2, varscan2
- ATP2A3 | c.180C>A p.L60= | Silent (SNP) | VAF 99/316 reads (31%) | called by muse, mutect2, varscan2
- BCAN | c.1911C>T p.S637= | Silent (SNP) | VAF 91/355 reads (26%) | catalogued as COSV61256243; called by muse, mutect2, varscan2
- C1QTNF5 | c.90G>A p.G30= | Silent (SNP) | VAF 180/506 reads (36%) | called by muse, mutect2, varscan2
- C8A | c.1740G>A p.Q580= | Silent (SNP) | VAF 78/278 reads (28%) | called by muse, mutect2
- CACNA1E | c.6645C>T p.H2215= (on ENST00000367573 / NM_001205293.3; = p.H2172= on NM_000721.4) | Silent (SNP) | VAF 139/459 reads (30%) | catalogued as rs760207202; called by muse, mutect2, varscan2
- CACNA1H | c.2961C>A p.T987= | Silent (SNP) | VAF 114/388 reads (29%) | called by muse, mutect2, varscan2
- CATSPER1 | c.255G>A p.R85= | Silent (SNP) | VAF 145/507 reads (29%) | catalogued as COSV56413019; called by muse, mutect2, varscan2
- CCDC60 | c.1401G>A p.K467= | Silent (SNP) | VAF 82/286 reads (29%) | catalogued as rs571851641; called by muse, mutect2, varscan2
- CCDC86 | c.1077G>A p.K359= | Silent (SNP) | VAF 64/281 reads (23%) | called by muse, mutect2, varscan2
- CDH23 | c.708C>T p.F236= | Silent (SNP) | VAF 70/302 reads (23%) | called by muse, varscan2
- CHL1 | c.3192G>A p.E1064= (on ENST00000397491 / NM_001253387.1; = p.E1080= on NM_006614.4) | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as rs1483681707; called by muse, mutect2, varscan2
- CLDN4 | c.357C>T p.I119= | Silent (SNP) | VAF 110/473 reads (23%) | catalogued as rs570729167, COSV99936377; called by muse, mutect2, varscan2
- CLU | c.570C>A p.L190= | Silent (SNP) | VAF 116/395 reads (29%) | called by muse, mutect2, varscan2
- COL1A2 | c.789C>T p.P263= | Silent (SNP) | VAF 84/295 reads (28%) | catalogued as COSV51961070; called by muse, mutect2, varscan2
- CPT1B | c.1197C>T p.F399= | Silent (SNP) | VAF 66/267 reads (25%) | called by muse, mutect2, varscan2
- CYFIP1 | c.3012C>T p.I1004= | Silent (SNP) | VAF 77/434 reads (18%) | catalogued as rs760077367, COSV57415872; called by muse, mutect2, varscan2
- DNA2 | c.1248T>C p.S416= | Silent (SNP) | VAF 83/285 reads (29%) | called by muse, mutect2, varscan2
- DNAH9 | c.7083C>T p.I2361= | Silent (SNP) | VAF 88/332 reads (27%) | called by muse, mutect2, varscan2
- DNASE1L2 | c.534G>T p.A178= | Silent (SNP) | VAF 84/374 reads (22%) | called by muse, mutect2, varscan2
- DRD1 | c.183C>T p.F61= | Silent (SNP) | VAF 220/544 reads (40%) | catalogued as COSV67105052; called by muse, mutect2, varscan2
- DRG1 | c.855C>T p.I285= | Silent (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- DUSP10 | c.1353C>T p.F451= | Silent (SNP) | VAF 89/321 reads (28%) | catalogued as COSV100100105; called by muse, mutect2, varscan2
- DUSP9 | c.846G>A p.Q282= | Silent (SNP) | VAF 109/187 reads (58%) | called by muse, mutect2, varscan2
- F2 | c.222G>A p.L74= | Silent (SNP) | VAF 62/243 reads (26%) | catalogued as rs1004064124; called by muse, mutect2, varscan2
- FANCG | c.1710C>T p.L570= | Silent (SNP) | VAF 77/319 reads (24%) | called by muse, mutect2, varscan2
- FBXL18 | c.507C>T p.T169= | Silent (SNP) | VAF 141/453 reads (31%) | called by muse, mutect2, varscan2
- FBXO10 | c.699C>T p.I233= | Silent (SNP) | VAF 110/345 reads (32%) | called by muse, varscan2
- FEV | c.189C>T p.A63= | Silent (SNP) | VAF 35/443 reads (8%) | catalogued as rs755493413; called by muse, mutect2
- FHOD1 | c.2061C>T p.G687= | Silent (SNP) | VAF 82/248 reads (33%) | catalogued as COSV50758894; called by muse, mutect2, varscan2
- GABRB3 | c.675C>T p.F225= | Silent (SNP) | VAF 151/362 reads (42%) | catalogued as rs201004195; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF3 | c.477C>T p.T159= | Silent (SNP) | VAF 85/312 reads (27%) | called by muse, mutect2, varscan2
- GIMAP5 | c.618G>A p.V206= | Silent (SNP) | VAF 120/1500 reads (8%) | catalogued as rs375450342; called by muse, mutect2
- GIMAP8 | c.1620G>A p.E540= | Silent (SNP) | VAF 124/1403 reads (9%) | called by muse, mutect2
- GOLGA8T | c.1734G>A p.V578= | Silent (SNP) | VAF 96/807 reads (12%) | catalogued as rs1243661663; called by muse, mutect2, varscan2
- GPBAR1 | c.117C>T p.I39= | Silent (SNP) | VAF 124/453 reads (27%) | catalogued as rs770486496; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.4143G>A p.R1381= | Silent (SNP) | VAF 97/414 reads (23%) | called by muse, mutect2, varscan2
- HHAT | c.963C>T p.L321= | Silent (SNP) | VAF 76/321 reads (24%) | catalogued as COSV54790973; called by muse, mutect2, varscan2
- HMGB4 | c.243G>A p.K81= | Silent (SNP) | VAF 113/415 reads (27%) | catalogued as COSV53928748; called by muse, mutect2, varscan2
- HSP90AA1 | c.117G>A p.S39= | Silent (SNP) | VAF 68/238 reads (29%) | catalogued as rs746809598, COSV53489417; called by muse, mutect2, varscan2
- HSPB6 | c.9C>T p.I3= | Silent (SNP) | VAF 81/313 reads (26%) | catalogued as rs554865322; called by muse, mutect2, varscan2
- IBTK | c.567C>T p.S189= | Silent (SNP) | VAF 63/209 reads (30%) | catalogued as rs199566613; called by muse, mutect2, varscan2
- IDO2 | c.1110C>T p.L370= (on ENST00000389060; = p.L383= on NM_194294.2) | Silent (SNP) | VAF 101/334 reads (30%) | called by muse, mutect2, varscan2
- IGHE | c.1089G>A p.E363= | Silent (SNP) | VAF 86/354 reads (24%) | called by muse, mutect2, varscan2
- ITGAL | c.3165C>T p.L1055= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- ITPR2 | c.4233C>T p.T1411= | Silent (SNP) | VAF 57/209 reads (27%) | called by muse, mutect2, varscan2
- KDM6B | c.2478C>T p.S826= | Silent (SNP) | VAF 157/537 reads (29%) | called by muse, mutect2, varscan2
- KLRG2 | c.579G>A p.T193= | Silent (SNP) | VAF 147/1198 reads (12%) | catalogued as rs1267267963; called by muse, mutect2, varscan2
- KMT2B | c.4098C>T p.A1366= | Silent (SNP) | VAF 76/292 reads (26%) | called by muse, mutect2, varscan2
- KRT83 | c.78G>A p.R26= | Silent (SNP) | VAF 120/473 reads (25%) | called by muse, mutect2, varscan2
- LDLR | c.258C>T p.F86= | Silent (SNP) | VAF 75/276 reads (27%) | called by muse, varscan2
- LHX2 | c.930C>T p.L310= | Silent (SNP) | VAF 69/220 reads (31%) | catalogued as COSV101010082; called by muse, mutect2, varscan2
- LILRA1 | c.876G>A p.G292= | Silent (SNP) | VAF 124/797 reads (16%) | catalogued as rs145835913; called by muse, mutect2, varscan2
- LMX1A | c.1114C>T p.L372= | Silent (SNP) | VAF 90/286 reads (31%) | catalogued as COSV54227112, COSV54228049; called by muse, mutect2, varscan2
- LRP1B | c.6033C>T p.F2011= | Silent (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- MAP7 | c.1636C>T p.L546= | Silent (SNP) | VAF 120/397 reads (30%) | called by muse, mutect2, varscan2
- MAPT | c.879G>A p.V293= (on ENST00000262410 / NM_001377265.1; = p.V218= on NM_016835.4) | Silent (SNP) | VAF 156/589 reads (26%) | catalogued as rs1279617680; called by muse, mutect2, varscan2
- MECP2 | c.966C>T p.P322= | Silent (SNP) | VAF 107/205 reads (52%) | catalogued as rs1165796985; called by muse, mutect2, varscan2
- MIA2 | c.1200G>A p.R400= | Silent (SNP) | VAF 62/193 reads (32%) | called by muse, mutect2, varscan2
- MIA2 | c.1188C>T p.L396= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- MIS18BP1 | c.1284G>A p.R428= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as rs747464670; called by muse, mutect2, varscan2
- MORC1 | c.1449C>T p.I483= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs377208726; called by muse, varscan2
- MUC5B | c.871C>T p.L291= | Silent (SNP) | VAF 136/551 reads (25%) | catalogued as rs370370513; called by muse, mutect2, varscan2
- MYH1 | c.3921G>A p.R1307= | Silent (SNP) | VAF 61/237 reads (26%) | catalogued as rs1244228521; called by muse, mutect2, varscan2
- MYH15 | c.1968C>T p.F656= | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as rs779458266; called by muse, mutect2, varscan2
- MYO1A | c.1347C>T p.I449= | Silent (SNP) | VAF 63/231 reads (27%) | catalogued as rs760643735; called by muse, mutect2, varscan2
- NAV2 | c.3594G>A p.Q1198= (on ENST00000396087 / NM_001244963.2; = p.Q1175= on NM_145117.5) | Silent (SNP) | VAF 82/327 reads (25%) | called by muse, mutect2, varscan2
- NCK2 | c.945C>T p.S315= | Silent (SNP) | VAF 68/245 reads (28%) | catalogued as rs752615401, COSV99255733; called by muse, mutect2, varscan2
- NDNF | c.105G>A p.R35= | Silent (SNP) | VAF 82/354 reads (23%) | called by muse, mutect2, varscan2
- NHSL1 | c.3852C>T p.V1284= | Silent (SNP) | VAF 100/400 reads (25%) | catalogued as COSV58683913; called by muse, mutect2, varscan2
- NLRP7 | c.438C>T p.F146= | Silent (SNP) | VAF 129/464 reads (28%) | catalogued as rs971565866; called by muse, mutect2, varscan2
- NOC2L | c.336C>T p.S112= | Silent (SNP) | VAF 68/270 reads (25%) | called by muse, mutect2, varscan2
- NR2E3 | c.1038G>A p.Q346= | Silent (SNP) | VAF 183/562 reads (33%) | catalogued as COSV100489170; called by muse, mutect2, varscan2
- NRXN3 | c.1665C>T p.I555= (on ENST00000557594 / NM_001272020.2; = p.I979= on NM_004796.6) | Silent (SNP) | VAF 113/401 reads (28%) | catalogued as COSV55322616; called by muse, mutect2, varscan2
- NUCKS1 | c.672C>T p.P224= | Silent (SNP) | VAF 67/305 reads (22%) | called by muse, mutect2, varscan2
- NWD1 | c.1482C>T p.P494= | Silent (SNP) | VAF 100/367 reads (27%) | catalogued as COSV100343642, COSV60351202; called by muse, mutect2, varscan2
- OBSCN | c.11253C>T p.T3751= | Silent (SNP) | VAF 88/358 reads (25%) | called by muse, varscan2
- OR10G9 | c.336C>T p.F112= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as rs758351605, COSV100901513; called by muse, mutect2
- OR4K1 | c.636G>A p.L212= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as COSV53460460; called by muse, mutect2, varscan2
- PAX7 | c.1237C>T p.L413= | Silent (SNP) | VAF 145/454 reads (32%) | called by muse, mutect2, varscan2
- PHEX | c.1908G>A p.G636= | Silent (SNP) | VAF 77/148 reads (52%) | called by muse, mutect2, varscan2
- PLCG2 | c.3492C>T p.S1164= | Silent (SNP) | VAF 87/291 reads (30%) | catalogued as rs187113357; called by muse, mutect2, varscan2
- PRAMEF12 | c.282C>T p.R94= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as rs1376654323; called by muse, mutect2
- PTGER3 | c.1056C>T p.I352= | Silent (SNP) | VAF 99/359 reads (28%) | called by muse, mutect2, varscan2
- PTPN13 | c.5466C>T p.A1822= (on ENST00000411767 / NM_080683.3; = p.A1803= on NM_006264.3) | Silent (SNP) | VAF 53/243 reads (22%) | called by muse, mutect2, varscan2
- PTPN9 | c.438G>A p.R146= | Silent (SNP) | VAF 182/400 reads (46%) | called by muse, mutect2, varscan2
- REEP2 | c.546C>T p.T182= | Silent (SNP) | VAF 113/440 reads (26%) | called by muse, mutect2, varscan2
- RGSL1 | c.1392G>A p.V464= | Silent (SNP) | VAF 71/250 reads (28%) | catalogued as rs267598224, COSV54263734; called by muse, mutect2, varscan2
- RP1 | c.904T>C p.L302= | Silent (SNP) | VAF 53/209 reads (25%) | catalogued as COSV55119679; called by muse, mutect2, varscan2
- RREB1 | c.2037C>T p.I679= | Silent (SNP) | VAF 119/374 reads (32%) | catalogued as rs1344719929; called by muse, mutect2, varscan2
- SAFB | c.1437G>A p.V479= | Silent (SNP) | VAF 51/227 reads (22%) | called by muse, mutect2, varscan2
- SCN10A | c.1203G>A p.E401= | Silent (SNP) | VAF 112/380 reads (29%) | catalogued as rs1421961981; called by muse, mutect2, varscan2
- SIGLEC10 | c.1341G>A p.K447= | Silent (SNP) | VAF 92/432 reads (21%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1533G>A p.G511= | Silent (SNP) | VAF 78/330 reads (24%) | catalogued as COSV99693325; called by muse, mutect2, varscan2
- SLC24A3 | c.111C>T p.L37= | Silent (SNP) | VAF 134/435 reads (31%) | called by muse, varscan2
- SLC6A13 | c.1260C>T p.I420= | Silent (SNP) | VAF 66/318 reads (21%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1752C>T p.S584= | Silent (SNP) | VAF 110/295 reads (37%) | catalogued as rs1201150432, COSV53800260; called by muse, mutect2, varscan2
- SPOCD1 | c.2376C>T p.I792= | Silent (SNP) | VAF 58/210 reads (28%) | catalogued as rs769407145, COSV57094685; called by muse, mutect2, varscan2
- SPRED1 | c.132C>T p.V44= | Silent (SNP) | VAF 245/576 reads (43%) | catalogued as rs926984710; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.399C>T p.I133= | Silent (SNP) | VAF 116/383 reads (30%) | catalogued as COSV52535275; called by muse, mutect2, varscan2
- STXBP2 | c.192G>A p.R64= | Silent (SNP) | VAF 47/236 reads (20%) | called by muse, mutect2, varscan2
- SYNE1 | c.14424G>A p.T4808= (on ENST00000367255 / NM_182961.4; = p.T4737= on NM_033071.3) | Silent (SNP) | VAF 100/366 reads (27%) | catalogued as rs747679686; called by muse, mutect2, varscan2
- TAS2R39 | c.393C>T p.L131= | Silent (SNP) | VAF 72/628 reads (11%) | catalogued as rs762368730; called by muse, varscan2
- TBX15 | c.363C>T p.D121= (on ENST00000369429 / NM_001330677.2; = p.D15= on NM_152380.3) | Silent (SNP) | VAF 62/233 reads (27%) | called by muse, mutect2, varscan2
- TGDS | c.324C>T p.F108= | Silent (SNP) | VAF 56/220 reads (25%) | catalogued as rs143460763; called by muse, mutect2, varscan2
- TLN1 | c.5550C>T p.F1850= | Silent (SNP) | VAF 84/255 reads (33%) | catalogued as rs748787321, COSV59204675; called by muse, mutect2, varscan2
- TMEM211 | c.258C>T p.F86= (on ENST00000423535; = p.F15= on NM_001001663.3) | Silent (SNP) | VAF 131/527 reads (25%) | catalogued as COSV66954381; called by muse, mutect2, varscan2
- TNC | c.2241G>A p.R747= | Silent (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- TNRC18 | c.6010C>T p.L2004= | Silent (SNP) | VAF 126/515 reads (24%) | called by muse, mutect2, varscan2
- TNRC18 | c.4986C>T p.C1662= | Silent (SNP) | VAF 99/405 reads (24%) | catalogued as rs758597891; called by muse, mutect2, varscan2
- TNRC6B | c.2748G>A p.G916= | Silent (SNP) | VAF 69/303 reads (23%) | catalogued as COSV57292803; called by muse, mutect2, varscan2
- TRAK2 | c.2310C>T p.S770= | Silent (SNP) | VAF 97/367 reads (26%) | called by muse, mutect2, varscan2
- TRIML1 | c.1104C>T p.L368= | Silent (SNP) | VAF 99/376 reads (26%) | catalogued as COSV60193817, COSV60196653; called by muse, mutect2, varscan2
- TRMT5 | c.1467T>C p.L489= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as rs1246609578; called by muse, mutect2, varscan2
- TRPC7 | c.570C>T p.I190= | Silent (SNP) | VAF 221/538 reads (41%) | catalogued as COSV61464525; called by muse, mutect2, varscan2
- UBA2 | c.909C>T p.P303= | Silent (SNP) | VAF 55/248 reads (22%) | called by muse, mutect2, varscan2
- UBASH3A | c.1143G>A p.R381= | Silent (SNP) | VAF 53/228 reads (23%) | called by muse, mutect2, varscan2
- UBE2U | c.615C>T p.F205= | Silent (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- UBR4 | c.12057C>T p.I4019= | Silent (SNP) | VAF 72/287 reads (25%) | called by muse, mutect2, varscan2
- VIP | c.345C>T p.I115= | Silent (SNP) | VAF 54/195 reads (28%) | called by muse, mutect2, varscan2
- ZER1 | c.1300C>T p.L434= | Silent (SNP) | VAF 121/415 reads (29%) | called by muse, mutect2, varscan2
- ZFR2 | c.2136C>T p.S712= | Silent (SNP) | VAF 56/283 reads (20%) | catalogued as rs375273675; called by muse, mutect2, varscan2
- ZHX1 | c.1047G>A p.E349= | Silent (SNP) | VAF 82/323 reads (25%) | catalogued as rs762304004; called by muse, mutect2, varscan2
- ZNF488 | c.363G>A p.E121= | Silent (SNP) | VAF 147/496 reads (30%) | called by muse, mutect2, varscan2
- ZNF77 | c.1350C>T p.S450= | Silent (SNP) | VAF 102/373 reads (27%) | catalogued as COSV58822043; called by muse, mutect2, varscan2
- ZNF831 | c.789C>T p.T263= | Silent (SNP) | VAF 205/615 reads (33%) | catalogued as rs756594900, COSV100925950; called by muse, mutect2, varscan2
- ZNF90 | c.828G>A p.K276= | Silent (SNP) | VAF 74/344 reads (22%) | catalogued as rs782084777; called by muse, mutect2, varscan2
- ABCG1 | c.287-14520C>T | Intron (SNP) | VAF 67/253 reads (26%) | called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117559 C>T | 3'Flank (SNP) | VAF 168/441 reads (38%) | called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117560 C>T | 3'Flank (SNP) | VAF 158/418 reads (38%) | called by muse, varscan2
- ELOVL7 | c.64+3218G>A | Intron (SNP) | VAF 57/248 reads (23%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2350-870G>A | Intron (SNP) | VAF 70/263 reads (27%) | catalogued as COSV59446114; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-34942G>A | Intron (SNP) | VAF 49/212 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-20494C>T | Intron (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-15317G>A | Intron (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37606C>T | Intron (SNP) | VAF 118/399 reads (30%) | called by muse, mutect2, varscan2
- KLK14 | c.-36G>A | 5'UTR (SNP) | VAF 94/382 reads (25%) | catalogued as rs773425798; called by muse, mutect2, varscan2
- LMO7DN | n.426G>A | RNA (SNP) | VAF 74/345 reads (21%) | catalogued as rs947020043; called by muse, mutect2, varscan2
- MASP1 | c.1303+5544A>T | Intron (SNP) | VAF 123/412 reads (30%) | called by muse, mutect2, varscan2
- MLXIP | c.*127C>T | 3'UTR (SNP) | VAF 112/400 reads (28%) | called by muse, varscan2
- MLXIP | c.*128C>T | 3'UTR (SNP) | VAF 125/431 reads (29%) | catalogued as rs1346824610; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2892C>T | Intron (SNP) | VAF 74/241 reads (31%) | catalogued as COSV60172779; called by muse, varscan2
- NRXN1 | c.832+3293G>A | Intron (SNP) | VAF 18/81 reads (22%) | catalogued as rs886286288; called by muse, mutect2, varscan2
- PFDN4 | c.*519T>G | 3'UTR (SNP) | VAF 55/144 reads (38%) | called by muse, mutect2, varscan2
- RNF165 | c.61+38G>A | Intron (SNP) | VAF 84/403 reads (21%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*4934C>T | 3'UTR (SNP) | VAF 84/304 reads (28%) | called by muse, mutect2, varscan2
- VKORC1 | chr16:31095468 G>A | 5'Flank (SNP) | VAF 80/241 reads (33%) | called by muse, mutect2, varscan2
